Somatic mutation profile of tumor specimen TCGA-DU-A7T6-01A (aliquot TCGA-DU-A7T6-01A-11D-A33T-08) from TCGA case TCGA-DU-A7T6, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 73.3 years (26,766 days).
Specimen TCGA-DU-A7T6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99664cb0-65d6-4b4d-8fe5-9ae739d8f7fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7T6-10A (Blood Derived Normal), aliquot TCGA-DU-A7T6-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29dda216-a5df-4196-95b8-9006e40d4c69

The open-access MAF lists 115 somatic variants for this specimen: 99 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 15, Frame Shift Del 5, Nonsense Mutation 3, Splice Site 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 52/132 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AIFM1 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 44/404 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.279); catalogued as COSV99781297; called by muse, mutect2, varscan2
- ATP8A2 | c.2830C>T p.P944S | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54977608; called by muse, mutect2, varscan2
- BCLAF3 | c.1916G>A p.G639E (on ENST00000379682 / NM_001367774.1; = p.G610E on NM_198279.3) | Missense Mutation (SNP) | VAF 81/554 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100503358; called by muse, mutect2, varscan2
- BCR | c.1911C>G p.N637K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as COSV100006852; called by muse, mutect2, varscan2
- C5 | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1402957355, COSV56324454; called by muse, mutect2, varscan2
- CASS4 | c.1315G>A p.V439M | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV64385453; called by muse, mutect2, varscan2
- CCND1 | c.438C>G p.N146K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.131); catalogued as COSV99919717; called by muse, mutect2, varscan2
- CDH17 | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as rs1364385433, COSV99217780; called by muse, mutect2, varscan2
- CEACAM19 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV100715498; called by muse, mutect2, varscan2
- COL4A2 | c.1357A>G p.K453E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.893); catalogued as COSV100847434; called by muse, mutect2, varscan2
- COL5A1 | c.4169G>A p.G1390E | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880313; called by muse, mutect2, varscan2
- CRIP2 | c.462G>C p.E154D | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100231739; called by muse, mutect2, varscan2
- CTSG | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 24/163 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV99361641; called by muse, mutect2, varscan2
- CUL9 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs371301456, COSV99335779; called by muse, mutect2, varscan2
- DBR1 | c.1621G>A p.D541N | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV99604591; called by mutect2, varscan2
- DIAPH3 | c.2191C>T p.R731W (on ENST00000400324 / NM_001042517.2; = p.R468W on NM_030932.3) | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771964464, COSV99934075; called by muse, mutect2, varscan2
- ESPNL | c.1666C>G p.P556A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV58038309; called by muse, mutect2, varscan2
- FAT1 | c.7931A>G p.E2644G | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.137); catalogued as COSV101499529, COSV71675720; called by muse, mutect2, varscan2
- FGD3 | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV100490757; called by muse, varscan2
- FLNC | c.2478C>G p.N826K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100368492; called by muse, mutect2, varscan2
- FOXD1 | c.686C>G p.P229R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.267); catalogued as COSV100197732; called by muse, varscan2
- FRMPD2 | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV100563815; called by muse, mutect2, varscan2
- GDF7 | c.852C>G p.I284M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.353); catalogued as COSV99694178; called by muse, mutect2, varscan2
- GINS4 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 90/213 reads (42%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.939); catalogued as COSV99394614; called by muse, mutect2, varscan2
- HTR1F | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749605082, COSV100138137, COSV100138206; called by muse, mutect2, varscan2
- HTR5A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs1372976826, COSV55283469; called by muse, mutect2
- IGF1R | c.3956G>C p.R1319T | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99157168; called by muse, mutect2, varscan2
- IGHMBP2 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV99662387; called by muse, mutect2, varscan2
- IL1RAPL1 | c.997T>C p.S333P | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100149203; called by muse, mutect2, varscan2
- IL1RL1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs141061248; called by muse, mutect2, varscan2
- IL4R | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99405250; called by muse, mutect2, varscan2
- IZUMO1R | c.36G>A p.W12* | Nonsense Mutation (SNP) | VAF 13/189 reads (7%) | catalogued as rs775139282, COSV100126917; called by muse, mutect2
- KCNN2 | c.281G>C p.G94A (on ENST00000264773; = p.G306A on NM_021614.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.164); catalogued as COSV99300368; called by muse, mutect2, varscan2
- KIAA1217 | c.5443C>G p.L1815V | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV100286999; called by muse, mutect2, varscan2
- KIAA1549 | c.991C>G p.Q331E | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99651542; called by muse, mutect2, varscan2
- KRT36 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs781275139, COSV60204234; called by muse, mutect2, varscan2
- LEFTY2 | c.600G>C p.Q200H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs762406763, COSV64747939; called by muse, mutect2, varscan2
- LRRC18 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99630249; called by muse, mutect2, varscan2
- LRRC36 | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.005); catalogued as COSV99338973; called by muse, mutect2
- MAGEE1 | c.2840G>T p.G947V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV100819466; called by muse, mutect2, varscan2
- MBL2 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64758651; called by muse, mutect2, varscan2
- MBOAT2 | c.1471A>T p.N491Y | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100020489; called by muse, mutect2, varscan2
- MED13 | c.298T>C p.S100P | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.16); catalogued as COSV101181230; called by muse, mutect2
- MPHOSPH9 | c.2200A>G p.K734E | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100187009; called by muse, mutect2, varscan2
- MSH3 | c.2186A>G p.H729R | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV99434845; called by muse, mutect2, varscan2
- MTMR3 | c.3527G>C p.S1176T | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.438); catalogued as rs552767539, COSV100071172; called by muse, mutect2, varscan2
- MUC16 | c.2414G>C p.S805T | Missense Mutation (SNP) | VAF 97/286 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.139); catalogued as COSV101200642; called by muse, mutect2, varscan2
- MUC5B | c.11603C>G p.T3868S | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV101500609; called by muse, mutect2, varscan2
- NLRP13 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV100738395; called by muse, mutect2, varscan2
- NME8 | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99553656; called by muse, mutect2
- NOP58 | c.1249_1250del p.E417Kfs*3 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs768783326; called by mutect2, pindel, varscan2
- OR4B1 | c.402C>G p.I134M | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100535674; called by muse, mutect2, varscan2
- OR4N5 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs143406902; called by muse, mutect2, varscan2
- PCBP4 | c.850G>C p.A284P (on ENST00000322099 / NM_033010.2; = p.A241P on NM_020418.4) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100437122; called by muse, mutect2, varscan2
- PCDHB15 | c.1938C>G p.D646E | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV99179084; called by muse, mutect2, varscan2
- POLQ | c.7575G>A p.M2525I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs750113313, COSV99952626; called by muse, mutect2, varscan2
- PRDM8 | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV60203585; called by muse, mutect2, varscan2
- RAB35 | c.95C>G p.T32S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99984666; called by muse, mutect2, varscan2
- RBBP8NL | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99436855; called by muse, mutect2, varscan2
- RFX7 | c.178G>C p.V60L (on ENST00000559447 / NM_001368074.1; = p.V157L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100429149; called by muse, mutect2, varscan2
- RNF103 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1481613185, COSV99410297; called by muse, mutect2, varscan2
- ROBO2 | c.2780C>G p.S927C | Missense Mutation (SNP) | VAF 32/273 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164708, COSV100168856; called by muse, mutect2, varscan2
- RP1L1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100262241; called by muse, mutect2, varscan2
- S1PR4 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429453764, COSV99859308; called by muse, mutect2, varscan2
- SAMD12 | c.304A>C p.K102Q | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV59050803; called by muse, mutect2, varscan2
- SLC22A18 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100388915; called by muse, mutect2, varscan2
- SLC30A3 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs756037276, COSV51984265; called by muse, mutect2, varscan2
- SLC35F5 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as COSV99830152; called by muse, mutect2, varscan2
- SLIT1 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.284); catalogued as rs1167420133, COSV99822104; called by muse, mutect2, varscan2
- SMARCA1 | c.1369C>G p.R457G | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946417, COSV100946650; called by muse, mutect2, varscan2
- TAF1B | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99722381; called by muse, mutect2, varscan2
- TDGF1 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99947577; called by muse, mutect2, varscan2
- TENM2 | c.768C>G p.H256Q (on ENST00000518659 / NM_001122679.2; = p.H65Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); catalogued as COSV101319266; called by muse, mutect2, varscan2
- TIAM1 | c.4352C>T p.A1451V | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54560425, COSV99737676; called by muse, mutect2, varscan2
- TNFSF14 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs377428053; called by muse, mutect2, varscan2
- TRIM33 | c.2061G>T p.Q687H | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100635617; called by muse, mutect2, varscan2
- TTN | c.57752G>A p.G19251D (on ENST00000591111; = p.G11827D on NM_003319.4) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | PolyPhen probably damaging (1); catalogued as COSV100623178; called by muse, mutect2, varscan2
- UBFD1 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99563419; called by muse, mutect2, varscan2
- UNC13B | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs147799499; called by muse, mutect2, varscan2
- UQCR10 | c.131A>G p.Y44C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs1002449165, COSV100340823; called by muse, mutect2, varscan2
- VCX2 | c.300G>C p.Q100H | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV100400060; called by muse, mutect2, varscan2
- VWF | c.6562G>A p.G2188R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1036690966, COSV54631970, COSV99779225; called by muse, mutect2, varscan2
- WNT9A | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as COSV99688376; called by muse, mutect2, varscan2
- XKR4 | c.321C>G p.Y107* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV100533481; called by muse, mutect2
- ZAN | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 72/91 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759815650, COSV100770030; called by muse, mutect2, varscan2
- ZDHHC17 | c.1521C>G p.H507Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV100602206; called by muse, mutect2, varscan2
- ZNF143 | c.908A>C p.N303T | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.163); catalogued as COSV100217968; called by muse, mutect2, varscan2
- ZNF407 | c.6044G>C p.G2015A | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV100226596, COSV55268278; called by muse, mutect2, varscan2
- ZNF479 | c.698T>C p.I233T | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.233); catalogued as COSV100482934, COSV100482977; called by muse, mutect2, varscan2
- ZNF823 | c.614G>C p.S205T (on ENST00000341191 / NM_001297610.2; = p.S161T on NM_017507.2) | Missense Mutation (SNP) | VAF 34/227 reads (15%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as COSV100362580; called by muse, mutect2, varscan2
- ZSCAN16 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 66/335 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100481522; called by muse, mutect2, varscan2
- BAHCC1 | c.6518_6522del p.H2173Rfs*44 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | called by mutect2, pindel, varscan2
- BMS1 | c.3452_3456+29del p.X1151_splice | Splice Site (DEL) | VAF 10/109 reads (9%) | called by mutect2, pindel
- CIC | c.1817_1818del p.V606Gfs*83 | Frame Shift Del (DEL) | VAF 56/133 reads (42%) | called by pindel, varscan2
- JHY | c.1407_1410del p.R470Dfs*23 | Frame Shift Del (DEL) | VAF 26/178 reads (15%) | called by pindel, varscan2
- PPP2R3A | c.1473_1475del p.K491_F492delinsN | In Frame Del (DEL) | VAF 58/155 reads (37%) | called by mutect2, pindel, varscan2
- ST3GAL6 | c.618+2dup p.X206_splice | Splice Site (INS) | VAF 54/157 reads (34%) | called by mutect2, pindel, varscan2
- TANC2 | c.3257del p.L1086Yfs*19 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.2922C>T p.N974= | Silent (SNP) | VAF 54/147 reads (37%) | catalogued as COSV99685343; called by muse, mutect2, varscan2
- CDH8 | c.2163C>A p.V721= | Silent (SNP) | VAF 31/192 reads (16%) | catalogued as COSV100183457, COSV54847566; called by muse, mutect2, varscan2
- CLEC18A | c.432C>T p.N144= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs760360182, COSV99846961; called by muse, mutect2, varscan2
- CXCL1 | c.216C>G p.T72= | Silent (SNP) | VAF 29/222 reads (13%) | catalogued as COSV101203944; called by muse, mutect2, varscan2
- DCAF8L1 | c.1386C>G p.V462= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV101491514, COSV71595220; called by muse, mutect2, varscan2
- DNAH9 | c.5298C>T p.G1766= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as COSV99307193; called by muse, mutect2
- FLT4 | c.2340C>G p.V780= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56125702, COSV99988208; called by muse, mutect2
- LENG8 | c.132G>A p.Q44= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100457945; called by muse, mutect2
- LRRIQ4 | c.588C>T p.D196= | Silent (SNP) | VAF 47/168 reads (28%) | catalogued as rs1167416990, COSV61619016; called by muse, mutect2, varscan2
- MYO16 | c.3639G>C p.R1213= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV100696993; called by muse, mutect2, varscan2
- PKD1 | c.5406G>C p.V1802= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99238697; called by muse, mutect2, varscan2
- RYR3 | c.5568G>A p.A1856= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs199615159, COSV101213504; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINA1 | c.465G>A p.L155= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs1566756880, COSV100872167; called by muse, mutect2, varscan2
- TIGD4 | c.822G>A p.E274= | Silent (SNP) | VAF 36/239 reads (15%) | catalogued as COSV100428033; called by muse, mutect2, varscan2
- ZP4 | c.888C>T p.I296= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV63912698; called by muse, mutect2, varscan2
- TUBB7P | n.491T>C | RNA (SNP) | VAF 48/131 reads (37%) | called by muse, mutect2, varscan2
